Somatic mutation profile of tumor specimen 0E061S from CCDI case PBCUTH, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male.
Specimen 0E061S: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 17abfdab-c0af-43ad-bef9-0445964e7885.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0E062Y (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6874e0fc-864f-4325-83cb-1d9ae27dba75

The open-access MAF lists 4 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Intron 1, Nonsense Mutation 1, Missense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ITCH | c.2365G>T p.D789Y (on ENST00000262650 / NM_001257137.3; = p.D748Y on NM_031483.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/1123 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PRKDC | c.4822C>T p.R1608* | Nonsense Mutation (SNP) | VAF 32/798 reads (4%) | called by muse, mutect2
- DIDO1 | c.4998C>T p.G1666= | Silent (SNP) | VAF 24/351 reads (7%) | catalogued as COSV99825599; called by muse, mutect2
- AKNAD1 | c.1747-64G>A | Intron (SNP) | VAF 36/89 reads (40%) | catalogued as rs1216729162; called by muse, varscan2
